Somatic mutation profile of tumor specimen TCGA-69-7761-01A (aliquot TCGA-69-7761-01A-11D-2167-08) from TCGA case TCGA-69-7761, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 85.0 years (31,041 days).
Specimen TCGA-69-7761-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33dc49d5-7334-4a38-9c77-7fe22e60813b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-69-7761-10A (Blood Derived Normal), aliquot TCGA-69-7761-10A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e386d75-2dbc-4138-b3b0-106776179898

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 6, Frame Shift Del 3, Nonsense Mutation 3, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPK1 | c.3124A>T p.K1042* | Nonsense Mutation (SNP) | VAF 14/160 reads (9%) | catalogued as COSV51585236; called by muse, mutect2
- ARFGEF1 | c.3406G>T p.D1136Y | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51608937; called by muse, mutect2
- CD109 | c.2556+1G>T p.X852_splice | Splice Site (SNP) | VAF 12/44 reads (27%) | catalogued as COSV54649682; called by muse, mutect2, varscan2
- DPYSL2 | c.272A>G p.Q91R | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as rs113269672, COSV60783514; called by muse, mutect2, varscan2
- DRAM1 | c.704A>G p.N235S | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs61748066; called by muse, mutect2, varscan2
- FMN2 | c.3392C>T p.P1131L | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs201911169, COSV60421338; called by muse, varscan2
- FRYL | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 9/105 reads (9%) | catalogued as COSV51947661; called by muse, mutect2
- HECTD1 | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101237394, COSV67946817; called by muse, varscan2
- ID2 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs987769768, COSV52170014; called by muse, mutect2, varscan2
- IL26 | c.53T>A p.L18H | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV57489018; called by muse, mutect2, varscan2
- KCNA5 | c.1514T>C p.V505A | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52905875; called by muse, mutect2, varscan2
- MYT1 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1224565423, COSV60505485; called by muse, mutect2, varscan2
- OGT | c.746T>A p.L249H | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as COSV65480812; called by muse, mutect2
- PCLO | c.2931A>C p.Q977H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV61636316; called by muse, mutect2
- PLXNB1 | c.4721G>C p.R1574T | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1338784494, COSV56489844; called by muse, mutect2, varscan2
- RALGAPA2 | c.1460T>G p.F487C | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52498200; called by muse, mutect2
- ROBO2 | c.1513G>T p.V505L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100166937; called by mutect2, varscan2
- SKA1 | c.399T>A p.S133R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as COSV53278933; called by muse, mutect2
- SMG5 | c.571G>T p.V191L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.055); catalogued as COSV62437622; called by muse, mutect2, varscan2
- TTN | c.18812A>T p.D6271V (on ENST00000591111; = p.D5344V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | PolyPhen possibly damaging (0.775); catalogued as COSV60075091; called by muse, mutect2, varscan2
- UXT | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100243846, COSV100243923; called by muse, mutect2
- ZEB1 | c.2329C>G p.P777A | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as COSV58044315; called by muse, mutect2, varscan2
- ZFYVE16 | c.1043G>C p.S348T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV62015814; called by muse, varscan2
- ZNF74 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62620246; called by muse, mutect2, varscan2
- GLT8D1 | c.396_400del p.L133Rfs*8 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- LRRIQ1 | c.839del p.L280* | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- MTUS1 | c.1711del p.I571Lfs*38 | Frame Shift Del (DEL) | VAF 37/223 reads (17%) | called by mutect2, pindel, varscan2
- GLB1L3 | c.675G>A p.E225= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV66281683; called by muse, mutect2, varscan2
- ITSN1 | c.1581A>G p.L527= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs1167869864, COSV66083269; called by muse, mutect2, varscan2
- PHOSPHO2 | c.306G>T p.S102= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99775832; called by mutect2, varscan2
- PSG8 | c.1122A>T p.L374= | Silent (SNP) | VAF 31/317 reads (10%) | catalogued as COSV60611982; called by muse, mutect2
- RRP1 | c.939C>T p.R313= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs199611237, COSV71856824; called by mutect2, varscan2
- SCN10A | c.1011C>G p.T337= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV71861430; called by muse, mutect2, varscan2
- PNKD | c.236+1058C>T | Intron (SNP) | VAF 13/166 reads (8%) | catalogued as COSV99297972; called by muse, mutect2
